Somatic mutation profile of tumor specimen TCGA-44-2656-01A (aliquot TCGA-44-2656-01A-02D-A271-08) from TCGA case TCGA-44-2656, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.6 years (21,766 days).
Specimen TCGA-44-2656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efd20b42-06c3-4d61-96f2-430d60ac65f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-2656-10A (Blood Derived Normal), aliquot TCGA-44-2656-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a066b306-49fe-47c4-a19f-f86f40ada4d5

The open-access MAF lists 857 somatic variants for this specimen: 660 protein-altering or splice-affecting, 182 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 548, Silent 182, Nonsense Mutation 61, Splice Site 20, Frame Shift Del 17, Splice Region 8, Intron 5, RNA 5, Frame Shift Ins 4, 5'UTR 2, In Frame Del 1, 3'UTR 1.

Variants (750 of 857; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 71/215 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.786G>A p.W262* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | catalogued as COSV62929677; called by muse, mutect2, varscan2
- ABCA10 | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV52218722; called by muse, mutect2, varscan2
- ABCA13 | c.12366G>T p.K4122N | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV71284197; called by muse, mutect2, varscan2
- ABCA4 | c.426C>A p.H142Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV64671523; called by muse, mutect2, varscan2
- ABCA9 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV60621424, COSV60627170; called by muse, mutect2, varscan2
- ABCC9 | c.52G>C p.G18R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV53964291; called by muse, mutect2, varscan2
- AC105001.2 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as COSV59108476; called by muse, mutect2
- ACSL1 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55661049, COSV55666266; called by muse, mutect2, varscan2
- ACTG1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as COSV59509545, COSV59509810; called by muse, varscan2
- ADAM20 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV56454240; called by muse, mutect2, varscan2
- ADAM21 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as COSV50789069; called by muse, mutect2
- ADAMTS15 | c.1726G>A p.G576R | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs147190472; called by muse, mutect2
- ADAMTS16 | c.3591C>A p.C1197* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV56980510; called by muse, mutect2, varscan2
- ADCY5 | c.1909A>T p.I637F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59194995; called by muse, mutect2, varscan2
- ADCY6 | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57166513; called by muse, mutect2, varscan2
- ADGRG4 | c.3931C>T p.Q1311* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as rs1433246655, COSV54950883; called by muse, mutect2, varscan2
- ADGRL4 | c.844T>A p.F282I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66059758; called by muse, mutect2, varscan2
- ADGRV1 | c.6796G>T p.G2266C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67979644; called by muse, mutect2, varscan2
- AFF2 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | catalogued as COSV60656743, COSV60659025; called by muse, mutect2, varscan2
- AFF4 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV54792178; called by muse, mutect2, varscan2
- AGAP1 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs1463385072, COSV58318767; called by muse, mutect2
- AGL | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54048722, COSV54054032; called by muse, mutect2, varscan2
- AGO3 | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV55791675; called by muse, mutect2, varscan2
- AHNAK | c.8602G>T p.E2868* | Nonsense Mutation (SNP) | VAF 7/171 reads (4%) | catalogued as COSV57205592, COSV57221348; called by muse, mutect2
- AHNAK2 | c.14074G>A p.E4692K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV60909243; called by muse, mutect2, varscan2
- AHNAK2 | c.2839G>T p.G947C | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV60909246; called by muse, mutect2, varscan2
- ALDH1L1 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56411309; called by muse, mutect2, varscan2
- ALOX5 | c.437T>A p.M146K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65551322; called by muse, mutect2, varscan2
- ALPK2 | c.3485C>A p.A1162D | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV100864754, COSV64490735; called by muse, mutect2, varscan2
- AMER2 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as rs752722281, COSV100766157; called by mutect2, varscan2
- AP2A2 | c.2555A>T p.Q852L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV59958409; called by muse, mutect2, varscan2
- APIP | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53506143; called by muse, mutect2, varscan2
- APOB | c.2617C>A p.L873M | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51925712; called by muse, mutect2, varscan2
- APOBEC4 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58016983; called by muse, mutect2, varscan2
- APOBR | c.2839G>T p.A947S (on ENST00000431282; = p.A956S on NM_018690.4) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1486024392, COSV60489064; called by muse, mutect2, varscan2
- ARFIP1 | c.567G>T p.M189I (on ENST00000353617 / NM_001287432.1; = p.M157I on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV61883385, COSV61886434; called by muse, mutect2, varscan2
- ARHGAP25 | c.1380C>A p.S460R (on ENST00000409202 / NM_001007231.3; = p.S452R on NM_014882.3) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.348); catalogued as COSV54899273; called by muse, mutect2, varscan2
- ARHGAP33 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as rs139022184; called by muse, mutect2, varscan2
- ARMC5 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV51655112; called by muse, mutect2, varscan2
- ARMC5 | c.1085G>C p.R362P | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51655120, COSV51659726; called by muse, mutect2, varscan2
- ARSF | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63839074; called by muse, mutect2, varscan2
- ASB15 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99306291; called by muse, mutect2, varscan2
- ASPM | c.8315A>G p.Q2772R | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54125763; called by muse, mutect2
- ATP13A2 | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.046); catalogued as COSV58698526; called by muse, mutect2, varscan2
- ATP1A3 | c.2892G>T p.E964D (on ENST00000545399 / NM_001256214.2; = p.E951D on NM_152296.5) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV57485662; called by muse, mutect2, varscan2
- ATP1B4 | c.844A>G p.I282V (on ENST00000218008 / NM_001142447.3; = p.I278V on NM_012069.5) | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.02); catalogued as COSV54311501; called by muse, mutect2, varscan2
- ATP2A1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV63920115; called by muse, mutect2
- ATP2B3 | c.1206G>A p.W402* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV54841452; called by muse, mutect2, varscan2
- ATP4A | c.2542C>A p.R848S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52866115; called by muse, mutect2, varscan2
- ATXN1 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); catalogued as COSV55207197, COSV55209691; called by muse, mutect2, varscan2
- BABAM2 | c.851+1G>T p.X284_splice | Splice Site (SNP) | VAF 5/55 reads (9%) | catalogued as COSV59617839, COSV59626067; called by muse, mutect2
- BCAS1 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV65084225; called by mutect2, varscan2
- BCAS1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.669); catalogued as COSV65084231; called by muse, mutect2, varscan2
- BDP1 | c.1961A>T p.H654L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs754948193, COSV62429287; called by muse, mutect2, varscan2
- BICD1 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55675492, COSV55683113; called by muse, mutect2, varscan2
- BIN2 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV57203914; called by muse, mutect2, varscan2
- BORA | c.853T>A p.S285T (on ENST00000613797; = p.S210T on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.709); catalogued as COSV64694931; called by muse, mutect2, varscan2
- BRAF | c.1661T>C p.L554P (on ENST00000288602 / NM_001374244.1; = p.L514P on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56089486; called by muse, mutect2
- BRAT1 | c.881A>G p.H294R | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV61394381; called by muse, mutect2, varscan2
- BRINP3 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66515010; called by muse, mutect2, varscan2
- BRIP1 | c.3601A>G p.I1201V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1396175226, COSV51994991; called by muse, mutect2, varscan2
- BUB1B | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs587778144, COSV55010377; ClinVar: not provided; called by muse, mutect2, varscan2
- C22orf42 | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.567); catalogued as COSV66075359; called by muse, mutect2, varscan2
- C2orf78 | c.1831C>A p.Q611K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.52); catalogued as COSV68516564; called by muse, mutect2, varscan2
- C9orf64 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV59032188; called by muse, mutect2, varscan2
- CACNA1E | c.1924A>C p.T642P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62384172; called by muse, mutect2, varscan2
- CACNA1E | c.5791G>T p.G1931C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV62383371, COSV62384187; called by muse, mutect2, varscan2
- CADPS | c.1137C>G p.I379M | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV51869717; called by muse, mutect2, varscan2
- CALU | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV50823286, COSV99975725; called by muse, mutect2, varscan2
- CAMK4 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56663808; called by muse, mutect2, varscan2
- CARD11 | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62716163, COSV62716582; called by muse, varscan2
- CCDC136 | c.1894C>A p.Q632K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV52796854; called by muse, mutect2, varscan2
- CCDC171 | c.2564A>C p.K855T | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52634882; called by muse, mutect2, varscan2
- CCDC63 | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV57527263; called by muse, mutect2, varscan2
- CCDC9B | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66874819; called by muse, mutect2
- CCNO | c.1027T>C p.C343R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as rs750464287, COSV57004411; called by muse, mutect2, varscan2
- CCT8L2 | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as COSV63461753, COSV63464025; called by muse, mutect2, varscan2
- CD163 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775730, COSV63131323; called by muse, mutect2, varscan2
- CD163 | c.2959G>T p.G987W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775731; called by muse, mutect2, varscan2
- CD244 | c.785C>A p.T262N (on ENST00000368033 / NM_001166663.2; = p.T257N on NM_016382.4) | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.222); catalogued as rs1377239214, COSV59236441; called by muse, mutect2, varscan2
- CD244 | c.403G>T p.E135* (on ENST00000368033 / NM_001166663.2; = p.E130* on NM_016382.4) | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV59236463, COSV59237862; called by muse, mutect2, varscan2
- CD5L | c.895A>T p.K299* | Nonsense Mutation (SNP) | VAF 29/110 reads (26%) | catalogued as COSV63821247; called by muse, mutect2, varscan2
- CDC73 | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.045); catalogued as COSV66465322; called by muse, mutect2
- CDH1 | c.1378G>T p.V460L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV55728592; called by muse, mutect2, varscan2
- CDH12 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV66390889; called by muse, mutect2
- CDH24 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs1171193219, COSV57458935; called by muse, mutect2
- CEACAM18 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67282317, COSV67283582; called by muse, mutect2, varscan2
- CEP126 | c.15G>T p.R5S | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.668); catalogued as COSV54822265; called by muse, mutect2, varscan2
- CFAP299 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63871884; called by muse, mutect2, varscan2
- CFAP57 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV52539439; called by muse, mutect2, varscan2
- CFHR4 | c.249C>A p.C83* (on ENST00000367416 / NM_001201551.2; = p.C84* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 23/94 reads (24%) | catalogued as COSV52225316; called by muse, mutect2, varscan2
- CFHR5 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56818614; called by muse, mutect2, varscan2
- CHST13 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV60041502; called by muse, mutect2, varscan2
- CIB4 | c.197T>A p.F66Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56599510; called by muse, mutect2, varscan2
- CIC | c.1387A>G p.I463V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.93); catalogued as COSV50549051; called by muse, mutect2, varscan2
- CIP2A | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55417434; called by muse, mutect2, varscan2
- CIT | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV55861941; called by muse, mutect2, varscan2
- CLASP1 | c.4265A>T p.Q1422L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as COSV55315566; called by muse, mutect2, varscan2
- CLCN4 | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66465375; called by muse, mutect2
- CLDN14 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59772018; called by muse, mutect2, varscan2
- CNGB3 | c.1179-1G>T p.X393_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV60685706; called by muse, mutect2, varscan2
- CNOT1 | c.1041A>T p.E347D | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV57765739; called by muse, mutect2, varscan2
- CNTN2 | c.2914C>A p.P972T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV59348479; called by muse, mutect2, varscan2
- CNTN4 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV61868879; called by muse, mutect2, varscan2
- CNTNAP2 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62150646; called by muse, mutect2, varscan2
- CNTNAP4 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs762920106, COSV100269809; called by muse, mutect2, varscan2
- CNTNAP4 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100269812; called by muse, mutect2, varscan2
- COBL | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV54339812; called by muse, mutect2, varscan2
- COL15A1 | c.3032-1G>T p.X1011_splice | Splice Site (SNP) | VAF 13/172 reads (8%) | catalogued as COSV66641776; called by muse, mutect2
- COL25A1 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67647040; called by muse, mutect2
- COL27A1 | c.3338C>T p.P1113L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV61922285; called by muse, varscan2
- COL3A1 | c.282+1G>T p.X94_splice | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV58582976; called by muse, mutect2
- COL4A2 | c.2704G>T p.G902* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV64625481; called by muse, mutect2
- COL5A1 | c.1306del p.A436Rfs*122 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | catalogued as COSV65668523; called by mutect2, varscan2
- COL5A1 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65665879; called by muse, mutect2, varscan2
- COL5A1 | c.2148G>T p.E716D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV65665882; called by muse, mutect2, varscan2
- COL5A2 | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.781); catalogued as COSV100880708, COSV66407652; called by muse, mutect2, varscan2
- COL9A3 | c.1056C>A p.G352= | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as COSV59650849; called by muse, mutect2, varscan2
- CPEB1 | c.1621C>T p.Q541* (on ENST00000617958; = p.Q476* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV55617442; called by muse, varscan2
- CPED1 | c.2839C>A p.Q947K | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100120269; called by muse, mutect2, varscan2
- CRACD | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV51716175; called by muse, mutect2, varscan2
- CREB3L2 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as COSV57792636; called by muse, mutect2, varscan2
- CRISPLD1 | c.1231T>A p.S411T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV51544994; called by muse, mutect2
- CRISPLD2 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52277138; called by muse, mutect2, varscan2
- CROT | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58973012; called by muse, mutect2, varscan2
- CSMD2 | c.9173G>T p.W3058L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53885674; called by muse, mutect2, varscan2
- CSMD2 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.074); catalogued as COSV53885699, COSV53897184; called by muse, mutect2, varscan2
- CSMD3 | c.10628G>T p.G3543V (on ENST00000297405 / NM_001363185.1; = p.G3374V on NM_052900.3) | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52115921, COSV99834043; called by muse, mutect2, varscan2
- CSMD3 | c.4107A>T p.Q1369H (on ENST00000297405 / NM_001363185.1; = p.Q1265H on NM_052900.3) | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV52116030; called by muse, mutect2, varscan2
- CSMD3 | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52116072; called by muse, mutect2
- CSN3 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV59243600; called by muse, mutect2, varscan2
- CT83 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV64140819; called by muse, mutect2, varscan2
- CTNNA2 | c.2154G>T p.M718I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100559222, COSV58138215; called by muse, mutect2, varscan2
- CTNND2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV58869546; called by muse, mutect2, varscan2
- CUBN | c.10429C>A p.P3477T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1468596216, COSV64709163; called by muse, mutect2, varscan2
- CUBN | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV64702053; called by muse, mutect2
- CUX2 | c.2417C>T p.S806L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as rs1445106287, COSV55625959; called by muse, mutect2
- CYP4F3 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV55407556; called by muse, mutect2, varscan2
- DCAF8L1 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV71595155; called by muse, mutect2, varscan2
- DCUN1D1 | c.295A>G p.S99G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV53043841; called by muse, mutect2, varscan2
- DDC | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63564084; called by muse, mutect2, varscan2
- DEPDC7 | c.1263G>A p.K421= (on ENST00000241051 / NM_001077242.2; = p.K412= on NM_139160.2) | Splice Region (SNP) | VAF 16/66 reads (24%) | catalogued as COSV53806054; called by muse, mutect2, varscan2
- DGKB | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 52/165 reads (32%) | catalogued as COSV51765416; called by muse, mutect2, varscan2
- DIAPH3 | c.1699G>T p.E567* (on ENST00000400324 / NM_001042517.2; = p.E304* on NM_030932.3) | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV99932962; called by mutect2, varscan2
- DIO2 | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs766090858, COSV70444863, COSV70445145; called by muse, mutect2, varscan2
- DIP2C | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55148506; called by muse, mutect2, varscan2
- DISP3 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1263650241, COSV53821782; called by muse, mutect2
- DISP3 | c.3376-1G>T p.X1126_splice | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV53821800; called by muse, mutect2, varscan2
- DLL3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/120 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV52693610; called by muse, mutect2, varscan2
- DNAH9 | c.9245A>T p.Q3082L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52337591; called by muse, mutect2, varscan2
- DNER | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59161139; called by muse, mutect2
- DSCAM | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.434); catalogued as rs373921750; called by muse, mutect2, varscan2
- DSCAML1 | c.1894G>T p.E632* (on ENST00000321322; = p.E572* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV58383444; called by muse, mutect2, varscan2
- DUOX1 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV58477926; called by muse, mutect2, varscan2
- DYNC1H1 | c.6397G>T p.E2133* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV64134814; called by muse, mutect2
- DYRK4 | c.1337A>G p.K446R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50537998; called by muse, mutect2, varscan2
- EBF2 | c.996G>C p.R332S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV68776392, COSV68779949; called by muse, mutect2, varscan2
- EDIL3 | c.1398G>C p.R466S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV56882919; called by muse, mutect2, varscan2
- EDN3 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs142051051, COSV61107321; called by muse, mutect2, varscan2
- EHD3 | c.666C>A p.D222E | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV59029442; called by muse, mutect2
- EIF4A2 | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV56215789; called by muse, mutect2, varscan2
- ELF1 | c.1537C>G p.Q513E | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.137); catalogued as COSV53497380; called by muse, mutect2
- ELF2 | c.599C>G p.P200R (on ENST00000379550 / NM_001331036.2; = p.P140R on NM_006874.4) | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55491915; called by muse, mutect2
- EMILIN2 | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV54421597; called by muse, mutect2, varscan2
- ENAH | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV52865586, COSV52868416; called by muse, mutect2, varscan2
- EPHA5 | c.2188C>A p.Q730K | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56633773; called by muse, mutect2, varscan2
- EPHA6 | c.711C>A p.N237K | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV67561544; called by muse, mutect2, varscan2
- EPHA7 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65178175; called by muse, mutect2, varscan2
- EPX | c.171-2A>T p.X57_splice | Splice Site (SNP) | VAF 39/163 reads (24%) | catalogued as COSV56595278; called by muse, mutect2, varscan2
- EPYC | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53798686, COSV53800095; called by muse, mutect2, varscan2
- ERG | c.443A>C p.Q148P | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55727958; called by muse, mutect2, varscan2
- ERICH3 | c.604-1G>C p.X202_splice | Splice Site (SNP) | VAF 5/62 reads (8%) | catalogued as COSV58600961; called by muse, mutect2
- ETNPPL | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56594815, COSV56595625; called by muse, mutect2, varscan2
- EXOC5 | c.1600A>C p.T534P | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); catalogued as COSV61770256; called by muse, mutect2
- EXT2 | c.1654G>T p.G552C (on ENST00000343631; = p.G585C on NM_000401.3) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100640528, COSV59146368; called by muse, mutect2, varscan2
- EXT2 | c.1655G>T p.G552V (on ENST00000343631; = p.G585V on NM_000401.3) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100640529; called by muse, mutect2, varscan2
- F13A1 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.043); catalogued as COSV53554408; called by muse, mutect2, varscan2
- FAF1 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV65636875; called by muse, mutect2
- FAM120A | c.2287G>T p.D763Y | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52901843, COSV99464656; called by muse, mutect2, varscan2
- FAM171B | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV59001183; called by muse, mutect2, varscan2
- FAM47C | c.484G>C p.A162P | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV63724173, COSV63727538; called by muse, mutect2
- FAM47C | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.519); catalogued as rs1251517581, COSV63724190; called by muse, mutect2, varscan2
- FAM83C | c.603C>A p.Y201* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV65582262, COSV65584138; called by muse, mutect2, varscan2
- FBLIM1 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as rs140794901; called by muse, mutect2, varscan2
- FCRL4 | c.917T>A p.L306Q | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54860250; called by muse, mutect2, varscan2
- FCRLA | c.296C>A p.S99Y (on ENST00000367959; = p.S76Y on NM_032738.4) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99375736; called by muse, varscan2
- FER1L6 | c.4814C>A p.T1605N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV67548408; called by muse, mutect2, varscan2
- FHDC1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as COSV52598100; called by muse, mutect2, varscan2
- FHL1 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV61779961; called by muse, mutect2, varscan2
- FHL5 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV58735599; called by muse, mutect2, varscan2
- FLG | c.1882C>G p.Q628E | Missense Mutation (SNP) | VAF 170/491 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs779204654, COSV64237807; called by muse, mutect2, varscan2
- FRAS1 | c.5948T>A p.L1983Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53593821; called by muse, mutect2
- FREM1 | c.4389G>T p.Q1463H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV66518765; called by muse, mutect2, varscan2
- FSIP2 | c.18260C>A p.S6087Y | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100554334; called by muse, mutect2, varscan2
- FUT8 | c.611G>C p.C204S (on ENST00000360689 / NM_001371534.1; = p.C41S on NM_004480.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61280796; called by muse, mutect2, varscan2
- FYCO1 | c.259G>T p.G87W | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56114071; called by muse, mutect2, varscan2
- G2E3 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52838833; called by mutect2, varscan2
- GALC | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54323602; called by muse, mutect2, varscan2
- GANAB | c.1050G>T p.Q350H | Missense Mutation (SNP) | VAF 85/366 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60462469; called by muse, mutect2, varscan2
- GARNL3 | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59224143; called by muse, mutect2, varscan2
- GAS2 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53404911; called by muse, mutect2, varscan2
- GDNF | c.459G>T p.E153D | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV58478486; called by muse, mutect2, varscan2
- GJB1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as CM066092, COSV62139558; called by muse, mutect2, varscan2
- GLDC | c.2851T>C p.S951P | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58677039; called by muse, mutect2, varscan2
- GLRX3 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV58691719; called by muse, mutect2, varscan2
- GNAQ | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54108142; called by muse, mutect2, varscan2
- GPC5 | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV65581502, COSV65582941; called by muse, mutect2, varscan2
- GPR139 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV58501876; called by muse, mutect2, varscan2
- GPR141 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57731470; called by muse, mutect2, varscan2
- GPR63 | c.700A>C p.T234P | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs866908729, COSV57739865; called by muse, mutect2, varscan2
- GPR63 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs1168525347, COSV57739874; called by muse, mutect2, varscan2
- GRIA4 | c.2093C>A p.S698* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV56884676; called by muse, mutect2
- GRID1 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60016391, COSV60052524; called by muse, mutect2, varscan2
- GRIN2D | c.2480T>A p.I827N | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53517920; called by muse, mutect2, varscan2
- GRK2 | c.990C>G p.H330Q | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57950625, COSV57951172; called by muse, mutect2
- GRK5 | c.1453A>T p.T485S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as COSV64865769; called by muse, mutect2
- GRM8 | c.2096C>A p.T699N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV58807197; called by muse, mutect2, varscan2
- GRM8 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58807209, COSV58878853; called by muse, mutect2, varscan2
- GTPBP3 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as rs746303532, COSV50173654; called by muse, mutect2, varscan2
- HAS2 | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV58262359; called by muse, mutect2
- HDAC2 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV64037464; called by muse, mutect2, varscan2
- HDAC4 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV61860646; called by muse, mutect2, varscan2
- HEATR5A | c.4460C>A p.A1487E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as rs757014948, COSV66338870; called by muse, mutect2, varscan2
- HECW1 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as COSV67823496; called by muse, mutect2, varscan2
- HEMGN | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV52325428; called by muse, mutect2
- HEPH | c.1557G>T p.W519C (on ENST00000343002; = p.W252C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57960018; called by muse, mutect2, varscan2
- HES2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV64732231; called by muse, mutect2, varscan2
- HHATL | c.1011G>T p.T337= | Splice Region (SNP) | VAF 14/41 reads (34%) | catalogued as COSV55133017; called by muse, mutect2, varscan2
- HMCN1 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV54881632; called by muse, mutect2, varscan2
- HNF4G | c.1104C>A p.I368= (on ENST00000354370 / NM_001330561.2; = p.I415= on NM_004133.5) | Splice Region (SNP) | VAF 4/46 reads (9%) | catalogued as COSV62966208; called by muse, mutect2
- HNRNPD | c.777del p.K260Rfs*109 (on ENST00000313899 / NM_031370.3; = p.K260Rfs*60 on NM_002138.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 51/273 reads (19%) | catalogued as COSV100002762; called by mutect2, varscan2
- HOXA1 | c.205C>A p.H69N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.466); catalogued as COSV56065371; called by muse, mutect2, varscan2
- HOXA2 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as rs1278253439, COSV56065380; called by muse, mutect2, varscan2
- HOXA7 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV54216847, COSV99636727; called by muse, mutect2, varscan2
- HP1BP3 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391598; called by muse, mutect2
- HSPH1 | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.313); catalogued as COSV60710458; called by muse, mutect2, varscan2
- IFNA2 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.359); catalogued as COSV66505368, COSV66505777; called by muse, mutect2
- IGFBPL1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1186519875, COSV66617825; called by muse, mutect2
- IGLON5 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as rs201159850, COSV54534813; called by muse, mutect2, varscan2
- IGSF10 | c.7490C>A p.T2497K | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56370576; called by muse, mutect2, varscan2
- IGSF10 | c.3142G>T p.E1048* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | catalogued as COSV56782276, COSV56792468; called by muse, mutect2, varscan2
- IGSF5 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66029450; called by muse, varscan2
- IL25 | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59304981; called by muse, mutect2, varscan2
- ILF3 | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV99139430; called by muse, mutect2, varscan2
- INSL5 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs778970586, COSV58787976; called by muse, mutect2, varscan2
- INTS5 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs201064662, COSV57950488; called by muse, mutect2, varscan2
- INTU | c.2455G>T p.E819* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV58869828; called by muse, mutect2, varscan2
- IPO8 | c.3020C>A p.A1007E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV56239193, COSV56239949; called by muse, mutect2, varscan2
- IPO8 | c.323+1G>T p.X108_splice | Splice Site (SNP) | VAF 17/72 reads (24%) | catalogued as COSV56239957, COSV56244872; called by muse, mutect2, varscan2
- IQGAP2 | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs369302838, COSV57168962; called by mutect2, varscan2
- ISLR | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs780036106, COSV51433111; called by muse, mutect2, varscan2
- ISOC1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240441068, COSV51491188; called by muse, mutect2, varscan2
- ITGA2B | c.2077G>T p.A693S | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.802); catalogued as COSV52231435; called by muse, mutect2, varscan2
- ITIH2 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as rs141514196; called by muse, mutect2, varscan2
- JMY | c.2528G>T p.R843I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV68659603; called by muse, mutect2, varscan2
- JRK | c.1411G>C p.A471P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV70629562; called by muse, mutect2, varscan2
- KAT6B | c.1993+1G>T p.X665_splice | Splice Site (SNP) | VAF 11/47 reads (23%) | catalogued as COSV54743082; called by muse, mutect2, varscan2
- KATNAL1 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV66062713; called by muse, mutect2, varscan2
- KCNA4 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV60250931; called by muse, mutect2, varscan2
- KCNH1 | c.514G>T p.V172L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV55071630; called by muse, mutect2, varscan2
- KCNJ12 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV59164166; called by muse, mutect2, varscan2
- KCNK6 | c.484G>T p.G162C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54579015; called by muse, mutect2, varscan2
- KDM3A | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs895391110, COSV57218783; called by muse, mutect2, varscan2
- KDM3A | c.3685C>T p.Q1229* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV57218054, COSV57218797; called by muse, mutect2, varscan2
- KIAA0319 | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV65496762; called by muse, mutect2
- KIAA0895 | c.472G>T p.V158L (on ENST00000297063 / NM_001100425.2; = p.V107L on NM_015314.3) | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV51709169; called by muse, mutect2, varscan2
- KIAA1109 | c.12352G>T p.G4118C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV52664312; called by muse, mutect2, varscan2
- KIAA1549L | c.1835C>A p.T612N (on ENST00000321505; = p.T909N on NM_012194.3) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); catalogued as COSV55770406; called by muse, mutect2, varscan2
- KLHL1 | c.1753A>T p.S585C | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64767887; called by muse, mutect2
- KLHL20 | c.1293G>T p.E431D | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52940557; called by muse, mutect2, varscan2
- KLHL6 | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV100384738, COSV58064813; called by muse, mutect2, varscan2
- KLK4 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60675824, COSV60677017; called by muse, mutect2, varscan2
- KRT6A | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV58104048; called by muse, mutect2, varscan2
- KRTAP10-8 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 89/371 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV58166017, COSV58166627; called by muse, mutect2, varscan2
- LAMC1 | c.2042G>T p.G681V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51133675; called by muse, mutect2, varscan2
- LAMC3 | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63088959; called by muse, mutect2
- LELP1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64202309; called by muse, mutect2, varscan2
- LETMD1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.143); catalogued as COSV50396781; called by muse, mutect2, varscan2
- LGALS9 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV56348141; called by muse, mutect2, varscan2
- LGI3 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV60443023; called by muse, mutect2, varscan2
- LHCGR | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54293448; called by muse, varscan2
- LILRB1 | c.1631C>A p.S544* (on ENST00000427581; = p.S494* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 47/145 reads (32%) | catalogued as COSV61116402; called by muse, mutect2, varscan2
- LIPK | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV68200711; called by muse, mutect2, varscan2
- LONRF3 | c.1948G>T p.D650Y (on ENST00000371628 / NM_001031855.3; = p.D609Y on NM_024778.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100504266, COSV59150402; called by muse, mutect2, varscan2
- LOXL4 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53255527; called by muse, mutect2, varscan2
- LPA | c.4865A>T p.Q1622L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV60297972; called by muse, mutect2, varscan2
- LRAT | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV60476607; called by muse, mutect2, varscan2
- LRIT2 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60565398; called by muse, mutect2, varscan2
- LRIT2 | c.1240G>T p.G414* | Nonsense Mutation (SNP) | VAF 40/104 reads (38%) | catalogued as rs199824710, COSV100258534, COSV60564499; called by muse, mutect2, varscan2
- LRPPRC | c.3015G>C p.Q1005H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53234833; called by muse, mutect2, varscan2
- LRRC7 | c.3304A>G p.K1102E (on ENST00000651989 / NM_001370785.2; = p.K1069E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV50417079; called by muse, mutect2, varscan2
- LTBP1 | c.1102G>T p.G368C (on ENST00000404816 / NM_206943.4; = p.G42C on NM_000627.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63181350, COSV63190597; called by muse, mutect2, varscan2
- LTBP3 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); catalogued as rs1400831758, COSV57238921; called by muse, mutect2
- LZTR1 | c.1398del p.S467Afs*89 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as CM140928, COSV53145166; called by mutect2, pindel, varscan2
- LZTS2 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64650995; called by muse, mutect2, varscan2
- MAGEC1 | c.2095C>A p.L699I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV53569035; called by muse, mutect2, varscan2
- MCPH1 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761698331, COSV60910693; called by muse, mutect2, varscan2
- MEF2C | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100425521, COSV60926486; called by muse, mutect2, varscan2
- MEP1A | c.2179G>T p.A727S | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV57918341; called by muse, mutect2, varscan2
- METTL4 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55247144; called by muse, mutect2, varscan2
- MGAM | c.3422C>A p.S1141Y | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV72073861; called by muse, mutect2, varscan2
- MICAL3 | c.3970G>T p.V1324L | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); catalogued as COSV71588069; called by muse, mutect2, varscan2
- MLYCD | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV52304185; called by muse, mutect2
- MMP10 | c.1088G>T p.R363I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54245588; called by muse, mutect2
- MNDA | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV63740075; called by muse, mutect2
- MRGPRX3 | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV66933290; called by muse, mutect2, varscan2
- MSLN | c.705-2A>T p.X235_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV53499669; called by muse, mutect2, varscan2
- MUC16 | c.33710C>A p.S11237* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV67449711; called by muse, mutect2, varscan2
- MUC2 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs1488053760; called by muse, mutect2, varscan2
- MUC21 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs748992183, COSV100888839; called by muse, varscan2
- MUSK | c.2500C>A p.L834I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51878545; called by muse, mutect2, varscan2
- MXRA5 | c.2410T>G p.L804V | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54226312; called by muse, mutect2
- MYB | c.1828C>A p.P610T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV57196289; called by muse, mutect2, varscan2
- MYH1 | c.4809C>A p.S1603R | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56844561; called by muse, varscan2
- MYO1D | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV59008301; called by muse, mutect2, varscan2
- MYO1G | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV51853360; called by muse, mutect2, varscan2
- MYOM3 | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58390639; called by muse, mutect2, varscan2
- NAGPA | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | PolyPhen benign (0.097); catalogued as COSV56569394; called by muse, mutect2, varscan2
- NBAS | c.5139-1G>T p.X1713_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55714223; called by muse, mutect2, varscan2
- NBAS | c.4349G>T p.G1450V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55714234; called by muse, mutect2
- NBEA | c.3233C>A p.P1078Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.26); catalogued as COSV59764301; called by mutect2, varscan2
- NCAN | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.436); catalogued as COSV99386721; called by muse, mutect2, varscan2
- NDST4 | c.1814C>G p.T605R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52110805; called by muse, mutect2
- NEDD4 | c.2735A>G p.N912S (on ENST00000508342 / NM_001284338.1; = p.N493S on NM_006154.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59059163; called by muse, mutect2, varscan2
- NHSL2 | c.1930G>T p.V644L (on ENST00000510661; = p.V1010L on NM_001013627.2) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV65452562; called by muse, mutect2, varscan2
- NID1 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51615832; called by muse, mutect2, varscan2
- NID1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51615849; called by muse, mutect2, varscan2
- NIPAL3 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50230305; called by muse, mutect2, varscan2
- NLRP14 | c.3251A>T p.E1084V | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV55064700; called by muse, mutect2
- NLRP2 | c.2290G>T p.G764C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54752874; called by muse, mutect2, varscan2
- NLRP3 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as CM060243, CM071606, COSV60220950; called by muse, mutect2, varscan2
- NLRP4 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100015586, COSV56709094; called by muse, mutect2, varscan2
- NLRP4 | c.1267G>T p.G423W | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56709107, COSV56714256; called by mutect2, varscan2
- NMRK2 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV51454954, COSV99396383; called by muse, mutect2, varscan2
- NMUR1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.647); catalogued as rs775345754, COSV59403614; called by muse, mutect2, varscan2
- NNMT | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.79); catalogued as COSV55473096; called by muse, mutect2
- NOS1AP | c.1191G>T p.E397D | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV62632536; called by muse, mutect2, varscan2
- NOTCH4 | c.4183G>T p.D1395Y | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV66679167, COSV66679207; called by muse, mutect2, varscan2
- NPY2R | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.47); catalogued as COSV61527392; called by muse, mutect2, varscan2
- NRSN1 | c.166A>T p.R56W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as COSV65893720; called by muse, mutect2, varscan2
- NTAQ1 | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54873826, COSV54876634; called by muse, mutect2, varscan2
- NUF2 | c.276-1G>T p.X92_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV54842363; called by muse, mutect2, varscan2
- NUGGC | c.1886A>G p.K629R | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV58432892; called by muse, mutect2, varscan2
- NUGGC | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV58432905; called by muse, mutect2, varscan2
- NUP58 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67750980; called by muse, mutect2
- NYNRIN | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs775948701, COSV66841367; called by muse, mutect2, varscan2
- OBSCN | c.16484C>A p.S5495* | Nonsense Mutation (SNP) | VAF 19/125 reads (15%) | catalogued as COSV52747622; called by muse, mutect2, varscan2
- OGN | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99363999; called by muse, mutect2, varscan2
- OR13C4 | c.779C>A p.A260E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.442); catalogued as rs1231005102, COSV52926000; called by muse, mutect2, varscan2
- OR14A16 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV62926213; called by muse, mutect2, varscan2
- OR1J4 | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); catalogued as COSV61589602; called by muse, mutect2, varscan2
- OR1N2 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65460303; called by muse, mutect2, varscan2
- OR2B11 | c.822G>T p.Q274H | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV59509455; called by muse, mutect2, varscan2
- OR2C3 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63574549; called by muse, mutect2
- OR2G2 | c.467T>C p.I156T | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60739619; called by muse, mutect2, varscan2
- OR2G3 | c.753C>A p.F251L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60680996; called by muse, mutect2, varscan2
- OR2L3 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV63454631; called by muse, mutect2, varscan2
- OR2M7 | c.257T>A p.L86* | Nonsense Mutation (SNP) | VAF 98/366 reads (27%) | catalogued as COSV58738152; called by muse, mutect2, varscan2
- OR2M7 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV58738159; called by muse, mutect2, varscan2
- OR2T10 | c.122G>C p.W41S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100393641, COSV57896246; called by muse, mutect2, varscan2
- OR2T34 | c.614A>T p.Y205F | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV60899780, COSV60900889; called by muse, mutect2, varscan2
- OR2T8 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369963137, COSV60661777; called by muse, mutect2
- OR2W3 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64456220, COSV64456361, COSV64456545; called by muse, mutect2, varscan2
- OR2W3 | c.734T>A p.L245H | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64456227; called by muse, mutect2
- OR4A15 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV59033850, COSV59034664; called by muse, mutect2, varscan2
- OR4D5 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV58305900; called by muse, mutect2, varscan2
- OR4D6 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV55659131; called by muse, mutect2, varscan2
- OR51Q1 | c.885T>A p.S295R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV56178029; called by muse, mutect2, varscan2
- OR52K1 | c.859C>G p.P287A | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV56903092; called by muse, mutect2, varscan2
- OR5K3 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.158); catalogued as COSV67349767; called by muse, mutect2, varscan2
- OR6C1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101110430, COSV65572776; called by muse, mutect2, varscan2
- OR6K2 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV62743167; called by muse, mutect2, varscan2
- OR8J1 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57316855; called by muse, mutect2, varscan2
- OSBPL6 | c.2605G>T p.A869S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51912195; called by muse, mutect2, varscan2
- OTOA | c.2058+1G>T p.X686_splice (on ENST00000286149; = p.X672_splice on NM_144672.4) | Splice Site (SNP) | VAF 13/79 reads (16%) | catalogued as COSV53750157; called by muse, mutect2, varscan2
- OTP | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as COSV60568561; called by muse, mutect2, varscan2
- OXSM | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV55000854, COSV99772001; called by muse, mutect2, varscan2
- PALB2 | c.2956G>T p.D986Y | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55162891; called by muse, mutect2, varscan2
- PALD1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV54971230; called by muse, mutect2
- PAPLN | c.800G>C p.R267P (on ENST00000554301; = p.R240P on NM_173462.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.586); catalogued as COSV53724713, COSV99389246; called by muse, mutect2
- PAPPA2 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62774202; called by muse, mutect2, varscan2
- PAQR9 | c.377C>A p.A126E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV61417691, COSV61418890; called by muse, mutect2, varscan2
- PARP8 | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV55856668; called by muse, mutect2, varscan2
- PCDH10 | c.2843G>T p.G948V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52088555; called by muse, mutect2, varscan2
- PCDH17 | c.2504G>C p.S835T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV64972253; called by muse, mutect2
- PCDHB7 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV50755814, COSV50775321; called by muse, mutect2, varscan2
- PCDHGA8 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs756625630, COSV53908987; called by muse, mutect2, varscan2
- PCDHGA9 | c.2157G>T p.W719C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53909016; called by muse, mutect2, varscan2
- PCYT1B | c.611A>T p.D204V | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63264203; called by muse, mutect2, varscan2
- PDGFA | c.580G>T p.G194* | Nonsense Mutation (SNP) | VAF 13/198 reads (7%) | catalogued as COSV63279250; called by muse, mutect2
- PDIA2 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV51984142; called by muse, mutect2, varscan2
- PDILT | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs747898472, COSV56699985, COSV56701372; called by muse, mutect2, varscan2
- PDZD9 | c.395T>G p.V132G (on ENST00000424898 / NM_001363519.1; = p.V72G on NM_173806.4) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV51671039; called by muse, mutect2, varscan2
- PDZRN3 | c.2867G>T p.G956V | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747778714, COSV55192349, COSV99731424; called by muse, mutect2, varscan2
- PDZRN3 | c.2777G>C p.R926P | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55192373; called by muse, mutect2, varscan2
- PECR | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54733625; called by muse, mutect2, varscan2
- PHLDA1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV56996736, COSV56996832; called by muse, mutect2, varscan2
- PI4KB | c.300G>T p.E100D (on ENST00000368873 / NM_001369623.1; = p.E112D on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.584); catalogued as COSV55015593; called by muse, mutect2, varscan2
- PIP5K1A | c.343G>T p.V115L (on ENST00000368888 / NM_001135638.2; = p.V102L on NM_003557.3) | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV62957543; called by muse, mutect2, varscan2
- PKHD1L1 | c.8535C>A p.H2845Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV65738596; called by muse, mutect2, varscan2
- PKNOX2 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV53541886; called by muse, mutect2
- PLB1 | c.4050C>A p.F1350L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV59820331; called by muse, varscan2
- PLCB1 | c.3409G>T p.D1137Y | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100569763; called by muse, mutect2
- PLCE1 | c.2575C>A p.Q859K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV99593866; called by muse, mutect2, varscan2
- PLCE1 | c.2576A>G p.Q859R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV99593873; called by muse, mutect2, varscan2
- PLEC | c.11719G>A p.G3907S (on ENST00000322810 / NM_201380.4; = p.G3797S on NM_000445.5) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1444612790, COSV59609645; called by muse, mutect2, varscan2
- PLEKHG3 | c.2105A>G p.N702S (on ENST00000394691; = p.N758S on NM_001308147.2) | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs757599300, COSV55978066; called by muse, mutect2, varscan2
- PLPPR4 | c.926A>C p.Y309S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV64564647; called by muse, mutect2, varscan2
- PLXND1 | c.4994-1G>C p.X1665_splice | Splice Site (SNP) | VAF 22/64 reads (34%) | catalogued as COSV60709986; called by muse, mutect2, varscan2
- PPM1G | c.1305C>A p.F435L | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59768608; called by muse, mutect2
- PPP1R12B | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61113940; called by muse, mutect2, varscan2
- PPP2R1A | c.1115A>T p.Q372L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59042818; called by muse, mutect2, varscan2
- PPP3R2 | c.402C>A p.D134E | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV62451450; called by muse, mutect2
- PPP4R3A | c.2336G>T p.G779V (on ENST00000554943 / NM_001366432.1; = p.G766V on NM_001284280.1) | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.127); catalogued as COSV61503680; called by muse, mutect2, varscan2
- PRAMEF19 | c.1141A>G p.T381A | Missense Mutation (SNP) | VAF 36/432 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); catalogued as rs763111416; called by muse, mutect2
- PRDM16 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54580933, COSV54607748, COSV54607942; called by muse, mutect2
- PRDM5 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); catalogued as COSV53356651; called by mutect2, varscan2
- PRELP | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV58115097, COSV58116639; called by muse, mutect2, varscan2
- PRKCB | c.528C>A p.L176= | Splice Region (SNP) | VAF 12/96 reads (13%) | catalogued as COSV57768867; called by muse, mutect2, varscan2
- PRKD1 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59560745; called by muse, mutect2, varscan2
- PROC | c.549T>A p.C183* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV52164948; called by muse, mutect2, varscan2
- PRPF38B | c.559-1G>T p.X187_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | catalogued as COSV64223543; called by muse, mutect2, varscan2
- PRPS1L1 | c.373A>T p.I125F | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV72649831; called by muse, mutect2, varscan2
- PSD | c.1417G>C p.A473P | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV50042276, COSV50065773; called by muse, mutect2, varscan2
- PSG7 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as rs775658996, COSV68444433; called by muse, mutect2, varscan2
- PTAFR | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59536158, COSV59536571; called by muse, mutect2, varscan2
- PTCHD4 | c.2074G>C p.V692L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.84); catalogued as COSV59778280, COSV59779193; called by muse, mutect2, varscan2
- PTGFR | c.722G>C p.R241T | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as COSV66114511, COSV66116048; called by muse, mutect2, varscan2
- PTGFRN | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV67797915; called by muse, mutect2, varscan2
- PTPRZ1 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1029352780, COSV66431656; called by muse, mutect2, varscan2
- PUM2 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57578403; called by muse, mutect2
- PYDC1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as COSV57251708; called by muse, mutect2
- QTRT1 | c.682G>C p.G228R | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748388439, COSV51550332, COSV99139017; called by muse, mutect2, varscan2
- R3HDM1 | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51521501; called by muse, mutect2, varscan2
- RAB3C | c.377C>A p.T126N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.902); catalogued as COSV51432144; called by muse, mutect2, varscan2
- RAB3GAP2 | c.149del p.G50Efs*41 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as COSV52966745; called by mutect2, pindel, varscan2
- RABGEF1 | c.776G>T p.R259L (on ENST00000439720 / NM_001287061.2; = p.R246L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV53161033; called by muse, mutect2, varscan2
- RABL3 | c.463A>T p.T155S | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV56335162; called by muse, mutect2, varscan2
- RAG1 | c.2683G>T p.V895L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV55024101; called by muse, mutect2, varscan2
- RALGPS1 | c.1339G>T p.G447W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52217279; called by muse, mutect2, varscan2
- RALGPS2 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV100243628; called by muse, mutect2, varscan2
- RANGAP1 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as COSV62362614; called by muse, mutect2, varscan2
- RAPGEF2 | c.3487G>T p.V1163L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52425451; called by muse, mutect2, varscan2
- RAPGEF3 | c.848G>T p.W283L (on ENST00000389212; = p.W241L on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50198845; called by muse, mutect2, varscan2
- RASGRF2 | c.1996C>A p.L666M | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54124012; called by muse, varscan2
- RASGRF2 | c.2045T>C p.L682P | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54124024; called by muse, varscan2
- RASSF2 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369276882, COSV65081772; called by muse, mutect2, varscan2
- RBBP6 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV60503656; called by muse, mutect2, varscan2
- RBM47 | c.481A>T p.M161L | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55930810; called by muse, mutect2, varscan2
- RBM7 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as rs1197876807, COSV64955434; called by muse, mutect2, varscan2
- RCC2 | c.7A>T p.R3W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV64905359; called by muse, mutect2, varscan2
- RDH16 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV100660177, COSV62457935; called by muse, mutect2, varscan2
- REC114 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58521596; called by muse, mutect2, varscan2
- REG3A | c.374G>T p.S125I | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as COSV59408670; called by muse, varscan2
- RGS22 | c.2123A>G p.Y708C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760394259, COSV62658145; called by muse, varscan2
- RHOJ | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs921202045, COSV57456941; called by muse, mutect2, varscan2
- RICTOR | c.4258G>T p.G1420C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57118145, COSV57121123; called by muse, mutect2, varscan2
- RICTOR | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV57118160, COSV99704618; called by muse, mutect2, varscan2
- RIMS1 | c.379G>T p.G127W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53442305, COSV53450164; called by muse, mutect2, varscan2
- RIPOR2 | c.1906G>C p.D636H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52418052; called by muse, mutect2, varscan2
- ROR2 | c.1821del p.S608Afs*15 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | catalogued as COSV65219314; called by mutect2, pindel, varscan2
- RPS6KL1 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.19); catalogued as COSV63580733; called by muse, mutect2, varscan2
- RSPO2 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52639444; called by muse, mutect2, varscan2
- RUVBL1 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59475136; called by muse, mutect2, varscan2
- SAMHD1 | c.1090C>T p.H364Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.068); catalogued as rs761616206, COSV53428585; called by muse, mutect2, varscan2
- SCAF11 | c.2711G>T p.G904V | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV65475262; called by muse, mutect2, varscan2
- SCG2 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 27/120 reads (23%) | catalogued as COSV100544872, COSV59539229; called by muse, mutect2, varscan2
- SCN1A | c.2509G>T p.G837C (on ENST00000303395 / NM_001202435.3; = p.G826C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV57662590; called by mutect2, varscan2
- SCN9A | c.2822A>T p.Q941L (on ENST00000303354; = p.Q930L on NM_002977.3) | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV57602235; called by muse, mutect2, varscan2
- SCRN1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54128723; called by muse, mutect2
- SCRN1 | c.622G>C p.A208P | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54128739; called by muse, mutect2, varscan2
- SCYL1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs761461911, COSV54210822; called by muse, mutect2
- SEC13 | c.258G>C p.W86C (on ENST00000350697 / NM_183352.3; = p.W89C on NM_030673.4) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61601343, COSV61602328; called by muse, mutect2, varscan2
- SEC31A | c.3500C>A p.T1167N (on ENST00000355196 / NM_001318120.1; = p.T1128N on NM_016211.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV52342095; called by muse, mutect2, varscan2
- SEMA3A | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.08); catalogued as COSV54863214, COSV54870165; called by muse, mutect2, varscan2
- SERPINA9 | c.151T>A p.F51I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54073061; called by muse, mutect2, varscan2
- SERPINA9 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV54073079; called by muse, mutect2, varscan2
- SERTAD2 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.054); catalogued as COSV57639728; called by muse, mutect2, varscan2
- SETBP1 | c.3815G>C p.S1272T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV56314588; called by muse, mutect2, varscan2
- SEZ6L2 | c.1209-1G>A p.X403_splice (on ENST00000308713 / NM_001114099.3; = p.X333_splice on NM_012410.4) | Splice Site (SNP) | VAF 10/49 reads (20%) | catalogued as rs769341834, COSV58097601; called by muse, mutect2, varscan2
- SH3GL3 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs559656402, COSV61053890, COSV61056992; called by muse, mutect2, varscan2
- SHOC1 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV59498205; called by muse, mutect2, varscan2
- SHPRH | c.2378G>C p.R793P | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV51605525; called by muse, mutect2, varscan2
- SIGLEC10 | c.2062C>T p.Q688* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | catalogued as COSV59479537; called by muse, mutect2, varscan2
- SIGLEC8 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV58472444; called by muse, varscan2
- SIGLEC9 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51582875; called by muse, mutect2, varscan2
- SKAP2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV61721770; called by muse, mutect2, varscan2
- SLC10A2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as COSV55357451; called by muse, mutect2, varscan2
- SLC10A7 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV53880821; called by muse, mutect2
- SLC12A1 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57708450; called by muse, mutect2, varscan2
- SLC12A5 | c.1004C>T p.T335M (on ENST00000454036 / NM_001134771.2; = p.T312M on NM_020708.5) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs780957586, COSV54789531; called by muse, mutect2, varscan2
- SLC17A9 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1283808937, COSV64846909; called by muse, mutect2, varscan2
- SLC22A6 | c.683A>T p.Y228F | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.253); catalogued as COSV64559895; called by muse, mutect2, varscan2
- SLC26A3 | c.275T>C p.L92S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60639050; called by muse, mutect2
- SLC30A3 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV51984206; called by muse, mutect2, varscan2
- SLC44A1 | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.997); catalogued as COSV58262544; called by muse, mutect2, varscan2
- SLC4A3 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as rs766023938, COSV56091989; called by muse, mutect2, varscan2
- SLC5A11 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61740384; called by muse, mutect2, varscan2
- SLC5A7 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV50889271; called by muse, mutect2, varscan2
- SLC6A5 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV54224033, COSV54224296; called by muse, mutect2, varscan2
- SLCO2B1 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV56933378; called by muse, mutect2
- SLIT1 | c.2080G>A p.G694R | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56581393; called by muse, mutect2, varscan2
- SLITRK6 | c.1355C>A p.P452Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV68389526; called by muse, mutect2
- SMARCA4 | c.4015G>T p.E1339* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV60788531, COSV60806990; called by muse, mutect2
- SMARCAD1 | c.3020G>T p.G1007V | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV62773170; called by muse, mutect2, varscan2
- SMC4 | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58445575; called by muse, mutect2, varscan2
- SMOC1 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1455506717, COSV62759766, COSV62760557; called by muse, mutect2, varscan2
- SNIP1 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56165765; called by muse, mutect2, varscan2
- SORCS3 | c.982C>G p.R328G | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100865177, COSV63803722; called by muse, mutect2, varscan2
- SOX5 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV58620713; called by muse, mutect2
- SPEF2 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61544933; called by muse, mutect2
- SPEG | c.7937G>T p.R2646L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs201143360, COSV56664385, COSV56671387; called by muse, mutect2, varscan2
- SPN | c.99G>T p.L33F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.423); catalogued as COSV64070009; called by muse, mutect2, varscan2
- SPRR1B | c.195C>A p.C65* | Nonsense Mutation (SNP) | VAF 51/243 reads (21%) | catalogued as COSV61067471; called by muse, mutect2, varscan2
- SPTBN1 | c.6790G>T p.V2264L | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV61686131; called by muse, mutect2, varscan2
- SPTBN2 | c.901A>T p.M301L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs897181468, COSV59448114; called by muse, mutect2, varscan2
- SQSTM1 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV62434318; called by muse, mutect2, varscan2
- SRGAP2 | c.1646C>T p.A549V (on ENST00000624873 / NM_001170637.4; = p.A550V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV55333992; called by muse, mutect2, varscan2
- SRGAP2 | c.3161G>T p.G1054V (on ENST00000624873 / NM_001170637.4; = p.G1055V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); catalogued as COSV55334005; called by muse, mutect2, varscan2
- STARD13 | c.464G>T p.R155L (on ENST00000336934 / NM_001243476.3; = p.R37L on NM_052851.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55227681, COSV55227908; called by muse, mutect2, varscan2
- STARD7 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV61525174; called by muse, mutect2, varscan2
- STEAP4 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as COSV57328271; called by muse, mutect2, varscan2
- STIM1 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56152127; called by muse, mutect2, varscan2
- STK31 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63454440; called by muse, mutect2, varscan2
- STPG2 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV54787871; called by muse, mutect2, varscan2
- STXBP1 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1462181047, COSV64812224; called by muse, mutect2
- SULT2A1 | c.716T>A p.V239E | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV55764269; called by muse, mutect2, varscan2
- SYNPO2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs914334727, COSV61107476; called by muse, mutect2, varscan2
- SYT6 | c.1399G>T p.V467L (on ENST00000610222 / NM_001366225.1; = p.V382L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV65772698; called by muse, mutect2, varscan2
- SYTL2 | c.252A>T p.A84= | Splice Region (SNP) | VAF 47/126 reads (37%) | catalogued as COSV60356417; called by muse, mutect2, varscan2
- TAF1L | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54259118, COSV99644232; called by muse, mutect2, varscan2
- TAF1L | c.1791G>T p.Q597H | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV54262769, COSV99644233; called by muse, mutect2, varscan2
- TAS1R1 | c.2439C>A p.Y813* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as COSV59839437; called by muse, mutect2, varscan2
- TBX22 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV64785128; called by muse, mutect2
- TBX3 | c.1069G>T p.A357S (on ENST00000257566 / NM_016569.4; = p.A337S on NM_005996.4) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.124); catalogued as COSV57469656; called by muse, mutect2, varscan2
- TBX5 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59858835; called by muse, mutect2
- TCEA2 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as COSV58657286; called by muse, mutect2, varscan2
- TENM2 | c.1729C>A p.P577T (on ENST00000518659 / NM_001122679.2; = p.P345T on NM_001080428.3) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV69124046; called by muse, mutect2, varscan2
- TENM4 | c.2570G>T p.C857F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53612327; called by muse, mutect2, varscan2
- TESPA1 | c.889C>T p.R297* (on ENST00000316577 / NM_001098815.3; = p.R159* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 28/50 reads (56%) | catalogued as rs764857918, COSV57257521; called by muse, mutect2, varscan2
- TET1 | c.5352G>T p.K1784N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1454252323, COSV65382496; called by muse, mutect2, varscan2
- TET1 | c.5698G>T p.G1900C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65382501; called by muse, mutect2, varscan2
- TEX13B | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57202254; called by muse, mutect2, varscan2
- TEX2 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 29/110 reads (26%) | catalogued as COSV51978037; called by muse, mutect2, varscan2
- TFAP2B | c.212C>A p.P71Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV53825533; called by muse, mutect2, varscan2
- TFPT | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV58084653; called by muse, mutect2, varscan2
- TG | c.7620C>A p.Y2540* | Nonsense Mutation (SNP) | VAF 33/93 reads (35%) | catalogued as COSV55067077; called by muse, mutect2, varscan2
- TGFBR3 | c.2278G>T p.E760* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as COSV53022438; called by muse, mutect2, varscan2
- TGM4 | c.1597C>A p.Q533K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV56092980; called by muse, mutect2
- TGM7 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.923); catalogued as COSV71772602; called by muse, mutect2, varscan2
- THSD7A | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV70261105; called by muse, mutect2, varscan2
- TIGD4 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV100427862, COSV58549072; called by muse, mutect2
- TIMELESS | c.3454G>T p.E1152* | Nonsense Mutation (SNP) | VAF 93/240 reads (39%) | catalogued as COSV57509473; called by muse, mutect2, varscan2
- TKTL2 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54917715, COSV54919539; called by muse, mutect2, varscan2
- TLL1 | c.1963A>T p.R655* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV50263459, COSV50321640; called by muse, mutect2, varscan2
- TNC | c.3435T>G p.Y1145* | Nonsense Mutation (SNP) | VAF 18/244 reads (7%) | catalogued as COSV60781231; called by muse, mutect2
- TOPORS | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.202); catalogued as COSV62116305; called by muse, mutect2, varscan2
- TP53 | c.217del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 42/140 reads (30%) | catalogued as CD109812, COSV53023392, COSV53359933, COSV53361901, COSV53625318, COSV99409681; called by mutect2, varscan2
- TPO | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.156); catalogued as COSV61096265; called by muse, mutect2, varscan2
- TRAM1 | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV51596845; called by muse, mutect2, varscan2
- TRAM1L1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV60291369; called by muse, mutect2, varscan2
- TRANK1 | c.8203G>A p.G2735S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs765419817, COSV57143035, COSV57160597; called by muse, mutect2, varscan2
- TRIB2 | c.1001T>A p.M334K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.05); catalogued as COSV99330952; called by muse, mutect2, varscan2
- TRIB2 | c.1002G>T p.M334I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV50223936, COSV99330959; called by muse, mutect2, varscan2
- TRIM55 | c.1236G>A p.Q412= | Splice Region (SNP) | VAF 11/77 reads (14%) | catalogued as COSV99396586; called by muse, mutect2, varscan2
- TRIM55 | c.1236+1G>T p.X412_splice | Splice Site (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52545690, COSV99396591; called by muse, mutect2, varscan2
- TRIM71 | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67470262; called by muse, mutect2
- TRIM75P | c.1316C>A p.T439N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.421); catalogued as COSV72295808; called by muse, mutect2, varscan2
- TRIML1 | c.1386C>A p.C462* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as COSV60193516; called by muse, mutect2, varscan2
- TRMT2B | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV58618627; called by muse, mutect2, varscan2
- TRPM4 | c.2953G>T p.V985L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV53259986; called by muse, mutect2, varscan2
- TRPV5 | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV54683514; called by muse, mutect2
- TSPAN33 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV56825583; called by muse, mutect2, varscan2
- TTN | c.5211G>C p.E1737D (on ENST00000591111; = p.E1691D on NM_003319.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | PolyPhen probably damaging (0.99); catalogued as COSV59914916; called by muse, mutect2
- TXNDC12 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV65412962; called by muse, mutect2, varscan2
- UCMA | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66321313, COSV66321927; called by muse, mutect2, varscan2
- UGDH | c.166G>T p.G56* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV57096859; called by muse, mutect2, varscan2
- UGT2A1 | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54138765; called by muse, mutect2
- UGT2A3 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52359053; called by muse, mutect2, varscan2
- ULK4 | c.1799C>A p.A600D | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as COSV57200805; called by muse, mutect2, varscan2
- UMOD | c.139G>T p.V47F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV56774007; called by muse, varscan2
- UMODL1 | c.1411G>T p.V471L | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs150059583, COSV61159437; called by muse, mutect2, varscan2
- UNC13C | c.2645T>A p.M882K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV52848094; called by muse, mutect2, varscan2
- UNC5B | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as COSV58974958; called by muse, mutect2, varscan2
- USF3 | c.4761C>A p.N1587K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV57070355; called by muse, mutect2, varscan2
- USH2A | c.1493C>A p.T498N | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV56335038; called by muse, mutect2, varscan2
- USHBP1 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as rs528877755, COSV53102475; called by muse, mutect2, varscan2
- USP6 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51476237; called by muse, mutect2, varscan2
- VPS13C | c.2662A>G p.T888A (on ENST00000644861 / NM_020821.3; = p.T845A on NM_017684.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV51126776; called by muse, mutect2, varscan2
- VPS16 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66792615; called by muse, mutect2, varscan2
- VPS35 | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV54477333; called by muse, varscan2
- VSNL1 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV54597763; called by muse, mutect2, varscan2
- VSTM2A | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as COSV56492534; called by muse, mutect2, varscan2
- VSTM2A | c.372A>T p.L124F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56492547; called by muse, mutect2, varscan2
- VWA5A | c.1625+1G>C p.X542_splice | Splice Site (SNP) | VAF 6/120 reads (5%) | catalogued as COSV64412069; called by muse, mutect2
- VWF | c.2974G>T p.V992L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54613271; called by muse, mutect2, varscan2
- WARS2 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV52476213; called by muse, mutect2, varscan2
- WDR27 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61205048; called by muse, mutect2, varscan2
- WDR36 | c.1610-1G>T p.X537_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | catalogued as COSV72605091; called by muse, mutect2
- WNK4 | c.2117A>C p.D706A | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55901944; called by muse, mutect2
- YARS2 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV61401423; called by muse, mutect2, varscan2
- YIPF7 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60656114; called by muse, mutect2, varscan2
- ZAN | c.2306C>A p.S769Y | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV61805831; called by muse, mutect2, varscan2
- ZBED4 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53464082; called by muse, mutect2, varscan2
- ZBTB21 | c.2044C>A p.L682I | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.963); catalogued as COSV60403299, COSV60404906; called by muse, mutect2, varscan2
- ZC3H6 | c.2663C>G p.P888R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV59666282; called by muse, mutect2, varscan2
- ZEB1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as rs963030640, COSV100313658, COSV58037936; called by muse, mutect2, varscan2
- ZFHX4 | c.7613T>C p.M2538T | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV50550614; called by muse, mutect2, varscan2
- ZFHX4 | c.9954G>C p.Q3318H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.997); catalogued as COSV50550974; called by muse, mutect2
- ZFPM2 | c.2114A>G p.H705R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65872742; called by muse, mutect2, varscan2
- ZMYND11 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as COSV59076674; called by muse, mutect2, varscan2
- ZNF236 | c.5334C>G p.Y1778* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV53483061, COSV53483402; called by muse, mutect2
- ZNF268 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99934759; called by muse, mutect2, varscan2
- ZNF268 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV99934762; called by muse, mutect2, varscan2
- ZNF285 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as COSV58408173; called by muse, mutect2
- ZNF292 | c.2751G>T p.L917F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.188); catalogued as COSV60536307; called by muse, mutect2, varscan2
- ZNF592 | c.571G>C p.V191L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV55435363; called by muse, mutect2, varscan2
- ZNF683 | c.1252C>G p.R418G (on ENST00000403843; = p.R398G on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62873582, COSV62874562; called by muse, mutect2, varscan2
- ZNF713 | c.198G>T p.E66D (on ENST00000633730 / NM_001366796.2; = p.E79D on NM_182633.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV68887878; called by muse, mutect2
- ZNF804B | c.1635G>T p.W545C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); catalogued as COSV60818633; called by muse, mutect2, varscan2
- ZNF831 | c.1175C>A p.A392E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756694854, COSV64037437; called by muse, varscan2
- ZNF831 | c.4238C>G p.T1413S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV64037978; called by muse, varscan2
- ZP1 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV53923401, COSV53923449; called by muse, mutect2, varscan2
- ZSCAN18 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV53730179; called by muse, mutect2, varscan2
- AHNAK2 | c.16224del p.T5409Lfs*2 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.5152del p.Q1718Rfs*5 | Frame Shift Del (DEL) | VAF 26/252 reads (10%) | called by mutect2, varscan2
- BIRC6 | c.4685_4693del p.E1562_P1565delinsA | In Frame Del (DEL) | VAF 10/120 reads (8%) | called by mutect2, pindel
- CYP26A1 | c.641dup p.E215Rfs*119 | Frame Shift Ins (INS) | VAF 33/123 reads (27%) | called by pindel, varscan2
- DISP3 | c.2333C>A p.A778D | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FBXO43 | c.1227_1230del p.R410Qfs*12 | Frame Shift Del (DEL) | VAF 16/176 reads (9%) | called by mutect2, pindel
- FCGBP | c.814C>A p.Q272K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FNBP4 | c.343del p.D115Tfs*13 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- HP1BP3 | c.1204G>T p.G402W | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHG1 | c.672G>C p.G224= | Splice Region (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGKV2D-24 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- KRTAP26-1 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2
- LILRA6 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LY75 | c.5054G>A p.G1685E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2
- MIXL1 | c.502del p.T168Rfs*4 | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- MUC5B | c.10047del p.S3350Pfs*13 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel
- PRH2 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2
- RSPH10B | c.184del p.Q62Kfs*17 | Frame Shift Del (DEL) | VAF 13/78 reads (17%) | called by mutect2, varscan2
- RTL4 | c.801_802delinsA p.P268Qfs*60 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | called by pindel, varscan2*
- SAMD9L | c.465del p.K155Nfs*2 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2
- STAB2 | c.5294dup p.L1765Ffs*29 | Frame Shift Ins (INS) | VAF 49/104 reads (47%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.1044G>T p.W348C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- TLL2 | c.522dup p.S175Efs*7 | Frame Shift Ins (INS) | VAF 6/36 reads (17%) | called by mutect2, pindel
- TRAV12-2 | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRAV13-1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- TRAV22 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TRBV4-2 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS13B | c.7232_7245del p.I2411Rfs*23 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel
- VWC2 | c.7A>T p.S3C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- WDR35 | c.2616_2617del p.C872* (on ENST00000345530 / NM_001006657.2; = p.C861* on NM_020779.4) | Nonsense Mutation (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- ZBTB17 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZFHX3 | c.536dup p.K180Qfs*30 | Frame Shift Ins (INS) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- ZNF831 | c.1126del p.E376Rfs*158 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by pindel, varscan2
- ADCY8 | c.3126C>A p.A1042= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV53898358, COSV53911273; called by muse, mutect2, varscan2
- ADPRHL1 | c.72G>A p.K24= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV60260782; called by muse, mutect2, varscan2
- AGBL1 | c.2272C>A p.R758= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV66850612, COSV66852202; called by muse, mutect2, varscan2
- ALDH1L1 | c.744G>C p.T248= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV56411317, COSV56415451; called by muse, varscan2
- ANO6 | c.2056C>T p.L686= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV57657696; called by muse, mutect2, varscan2
- APOB | c.3144C>A p.T1048= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV51925700; called by muse, mutect2, varscan2
- ARHGAP6 | c.1761C>A p.I587= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV57292426, COSV57304386; called by muse, mutect2, varscan2
- ARHGEF28 | c.2484A>T p.A828= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV55248680; called by muse, mutect2, varscan2
- ASB10 | c.672G>T p.R224= (on ENST00000420175 / NM_001142459.2; = p.R209= on NM_080871.4) | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV51994634, COSV51997282; called by muse, mutect2, varscan2
- ASB15 | c.324C>A p.T108= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99306298; called by muse, mutect2, varscan2
- B3GNT7 | c.381G>C p.P127= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV55005970; called by muse, mutect2, varscan2
- BBS9 | c.2262G>A p.A754= (on ENST00000242067 / NM_001348036.1; = p.A714= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs751886707, COSV54158541; called by muse, mutect2, varscan2
- BCL11B | c.2022G>C p.A674= (on ENST00000357195 / NM_001282237.2; = p.A603= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV61733882, COSV61734657; called by muse, mutect2, varscan2
- BEND2 | c.1188C>A p.G396= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV66215217, COSV66215543; called by muse, mutect2, varscan2
- BNIP2 | c.765A>T p.T255= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV51105222; called by muse, varscan2
- BOD1L1 | c.2568T>C p.G856= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV50007350; called by muse, mutect2, varscan2
- BPIFB1 | c.93C>T p.L31= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs766101557, COSV53605360; called by muse, mutect2, varscan2
- BRINP3 | c.396G>T p.G132= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV66515015; called by muse, mutect2, varscan2
- C1QB | c.141C>A p.P47= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV59245084; called by muse, mutect2
- C9orf131 | c.3216C>A p.P1072= | Silent (SNP) | VAF 35/177 reads (20%) | catalogued as COSV56609850; called by muse, mutect2, varscan2
- CALHM2 | c.9C>A p.A3= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV53294521; called by muse, mutect2, varscan2
- CD109 | c.294A>T p.A98= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV54646080; called by muse, mutect2, varscan2
- CD22 | c.2220C>A p.A740= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1389878115, COSV50049863, COSV50055705; called by muse, mutect2, varscan2
- CHD5 | c.4951C>T p.L1651= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs751895497, COSV52409119; called by muse, mutect2, varscan2
- CNTN2 | c.807C>A p.P269= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs926391066, COSV59348457; called by muse, mutect2, varscan2
- CNTN6 | c.1980A>C p.A660= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV63163799; called by muse, mutect2, varscan2
- COBL | c.1209G>T p.T403= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV54339823, COSV54353011; called by muse, mutect2, varscan2
- COL22A1 | c.1431C>A p.S477= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV57326454; called by muse, mutect2, varscan2
- COL3A1 | c.3381G>A p.Q1127= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV58582992; called by muse, mutect2, varscan2
- CPED1 | c.2838A>T p.L946= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as rs760984728, COSV100120268; called by muse, mutect2, varscan2
- CRAMP1 | c.1245G>T p.V415= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs1039586551, COSV99245706; called by muse, mutect2
- CSH2 | c.372C>G p.A124= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV100400163; called by muse, mutect2
- CSMD3 | c.2877A>T p.S959= (on ENST00000297405 / NM_001363185.1; = p.S855= on NM_052900.3) | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV52116045; called by muse, mutect2, varscan2
- CYB561A3 | c.222G>C p.G74= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV53651009; called by muse, mutect2, varscan2
- DACH2 | c.390C>A p.I130= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV64163065; called by muse, mutect2, varscan2
- EIF3F | c.171G>T p.A57= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100562501; called by muse, mutect2, varscan2
- ELOVL3 | c.453A>T p.T151= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as COSV64174185; called by muse, mutect2, varscan2
- ENTR1 | c.520C>T p.L174= (on ENST00000357365 / NM_001039707.2; = p.L151= on NM_006643.4) | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53740759; called by muse, mutect2, varscan2
- ERI3 | c.33G>A p.G11= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV64830366; called by muse, mutect2, varscan2
- ERN2 | c.1155A>G p.A385= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV56831909; called by muse, mutect2, varscan2
- ESR1 | c.828C>A p.G276= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as rs1296595449, COSV52783514; called by muse, mutect2, varscan2
- FAM135B | c.681C>T p.Y227= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV52709185; called by muse, mutect2, varscan2
- FAM71D | c.1056C>T p.T352= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV61294783; called by muse, mutect2, varscan2
- FAT3 | c.4860A>T p.L1620= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV53082578; called by muse, mutect2, varscan2
- FCRLA | c.252G>A p.Q84= (on ENST00000367959; = p.Q61= on NM_032738.4) | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV52684637; called by muse, varscan2
- FCRLA | c.297C>A p.S99= (on ENST00000367959; = p.S76= on NM_032738.4) | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99375741; called by muse, varscan2
- FOXD4L1 | c.1122A>T p.G374= | Silent (SNP) | VAF 26/150 reads (17%) | catalogued as COSV52073116; called by muse, mutect2, varscan2
- GABRB1 | c.1266G>T p.G422= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs773055387, COSV54972792; called by muse, mutect2, varscan2
- GPR132 | c.81C>A p.G27= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV61677663; called by muse, mutect2, varscan2
- GRM3 | c.627C>T p.N209= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV64468098; called by muse, mutect2, varscan2
- GRM8 | c.2367C>T p.T789= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV58807183; called by muse, mutect2
- GUCY2F | c.2967T>G p.V989= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV54299175; called by muse, mutect2, varscan2
- HOXA3 | c.912C>A p.T304= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV57825306; called by muse, mutect2, varscan2
- IFT80 | c.1521A>T p.T507= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV58445814; called by muse, mutect2, varscan2
- IGKV1-6 | c.96C>A p.S32= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as rs769768893; called by muse, varscan2
- IGKV5-2 | c.21C>G p.L7= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- IL27RA | c.564G>T p.L188= | Silent (SNP) | VAF 57/191 reads (30%) | catalogued as COSV54599375; called by muse, mutect2, varscan2
- INSC | c.1023G>T p.R341= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV65409114; called by muse, mutect2, varscan2
- ITIH1 | c.1311C>T p.H437= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV56252820; called by muse, mutect2, varscan2
- ITIH2 | c.1482C>A p.S494= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV64432194; called by muse, mutect2, varscan2
- KCNK18 | c.315C>T p.S105= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV57971140; called by muse, mutect2, varscan2
- KCTD3 | c.663G>C p.T221= | Silent (SNP) | VAF 30/174 reads (17%) | catalogued as COSV52064631; called by muse, mutect2, varscan2
- KIRREL3 | c.1401C>T p.R467= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV69383744; called by muse, mutect2, varscan2
- KRT5 | c.1281T>C p.D427= | Silent (SNP) | VAF 73/147 reads (50%) | catalogued as COSV52859265; called by muse, mutect2, varscan2
- LAMA2 | c.1485A>T p.G495= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV70340333; called by muse, mutect2, varscan2
- LBP | c.864G>T p.T288= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV54138957, COSV54139604; called by muse, varscan2
- LCE3D | c.6C>A p.S2= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as COSV64230585; called by muse, varscan2
- LCE4A | c.78C>T p.P26= | Silent (SNP) | VAF 37/194 reads (19%) | catalogued as COSV59266441; called by muse, mutect2, varscan2
- LGI2 | c.759C>T p.N253= | Silent (SNP) | VAF 26/116 reads (22%) | catalogued as COSV66122481, COSV66124315; called by muse, varscan2
- LHX9 | c.426C>A p.A142= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV61327373; called by muse, mutect2, varscan2
- LIG4 | c.2032C>T p.L678= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63596538; called by muse, mutect2, varscan2
- LRRTM1 | c.825G>T p.V275= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV54438791; called by muse, mutect2, varscan2
- LRRTM4 | c.1164C>T p.T388= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV69139170, COSV69141054; called by muse, mutect2, varscan2
- LSAMP | c.240G>T p.L80= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV61278341; called by muse, mutect2, varscan2
- LTB4R | c.726G>A p.L242= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV51864750; called by muse, mutect2, varscan2
- MAGEB6B | c.843G>A p.A281= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV69689749; called by muse, mutect2, varscan2
- MAN2A1 | c.1452G>C p.S484= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV54846921, COSV54847689; called by muse, mutect2
- MARK1 | c.204G>A p.K68= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV65065948; called by muse, mutect2
- MGAM | c.1848G>T p.A616= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV72073859; called by muse, mutect2
- MGAM | c.4527C>A p.T1509= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV72073863; called by muse, mutect2, varscan2
- MID1IP1 | c.96G>A p.V32= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs756537342, COSV61230421; called by muse, mutect2, varscan2
- MMEL1 | c.726G>A p.Q242= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV56519036; called by muse, mutect2, varscan2
- MSC | c.585T>A p.V195= | Silent (SNP) | VAF 255/704 reads (36%) | catalogued as COSV57696210; called by muse, mutect2, varscan2
- MUC17 | c.6198A>C p.T2066= | Silent (SNP) | VAF 28/219 reads (13%) | catalogued as COSV60281720; called by muse, mutect2, varscan2
- MYOM3 | c.3837C>T p.H1279= | Silent (SNP) | VAF 40/226 reads (18%) | catalogued as rs766135314, COSV58390623; called by muse, mutect2, varscan2
- NDRG2 | c.843C>A p.T281= (on ENST00000298687 / NM_001354570.1; = p.T267= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV53871883; called by muse, mutect2, varscan2
- NDST3 | c.1977C>A p.V659= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV56613946; called by muse, mutect2, varscan2
- NEB | c.6342C>T p.H2114= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as COSV50831892; called by muse, mutect2, varscan2
- NEGR1 | c.261G>T p.V87= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV60832704; called by muse, mutect2, varscan2
- NETO1 | c.882C>A p.G294= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV55002464; called by muse, mutect2, varscan2
107 further variants in this file (0 protein-altering or splice-affecting, 92 silent, 15 other) are not listed here.
